Somatic mutation profile of tumor specimen TCGA-52-7809-01A (aliquot TCGA-52-7809-01A-21D-2122-08) from TCGA case TCGA-52-7809, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.6 years (27,233 days).
Specimen TCGA-52-7809-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2901c67-2fc1-4dd8-9671-4b98e9dde789.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-52-7809-10A (Blood Derived Normal), aliquot TCGA-52-7809-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab276418-46f5-4cf0-8d30-2d6b87df753d

The open-access MAF lists 260 somatic variants for this specimen: 204 protein-altering or splice-affecting, 52 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 52, Nonsense Mutation 15, Splice Region 5, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 2, RNA 1, 5'Flank 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCC | c.1241C>A p.S414* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs200719554, COSV100002312, COSV56661456; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SDHC | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as rs201286421, CM080529, COSV61368710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 27/61 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.662C>G p.A221G | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99418965; called by muse, mutect2, varscan2
- ACTR6 | c.449G>C p.S150T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV99498550; called by muse, mutect2, varscan2
- ADAM22 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV99716366; called by muse, mutect2, varscan2
- ADCY1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99811704; called by muse, mutect2, varscan2
- ADGRV1 | c.6004A>T p.I2002L | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV101315707, COSV67978730, COSV67993122; called by muse, mutect2, varscan2
- ALDH1B1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV100890918; called by muse, mutect2, varscan2
- ALMS1 | c.12022G>T p.G4008W | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100041883; called by muse, mutect2
- AMPH | c.396+1G>T p.X132_splice | Splice Site (SNP) | VAF 29/242 reads (12%) | catalogued as COSV100341576; called by muse, mutect2, varscan2
- ANKRD55 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100591193; called by muse, mutect2, varscan2
- AOC2 | c.1817C>G p.P606R | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV99520079; called by muse, mutect2, varscan2
- APOO | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); catalogued as COSV101004886; called by muse, mutect2, varscan2
- ATP11C | c.3281G>A p.R1094K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100557680; called by muse, mutect2, varscan2
- BMP5 | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as rs1216211375, COSV100895861, COSV63706400; called by muse, mutect2, varscan2
- C12orf40 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs764478283, COSV100209837, COSV100209865; called by muse, varscan2
- C4orf50 | c.828G>A p.M276I (on ENST00000324058; = p.M1508I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV100135745; called by muse, mutect2
- CADM3 | c.91A>T p.S31C (on ENST00000368125 / NM_001127173.3; = p.S65C on NM_021189.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100930295; called by muse, mutect2, varscan2
- CCDC102A | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); catalogued as COSV99264993; called by muse, mutect2, varscan2
- CCDC141 | c.3694A>G p.M1232V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99836531; called by muse, mutect2, varscan2
- CCT3 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV99827215; called by muse, mutect2, varscan2
- CDH24 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99399381; called by muse, mutect2, varscan2
- CENPJ | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as COSV101121492; called by muse, mutect2, varscan2
- CEP152 | c.2447A>G p.Q816R | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100358664; called by muse, mutect2, varscan2
- CFAP43 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1489456373, COSV63851944, COSV63853785; called by muse, mutect2, varscan2
- CLDN6 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs1178755380, COSV100172112; called by muse, mutect2, varscan2
- CLEC9A | c.321C>T p.A107= | Splice Region (SNP) | VAF 10/95 reads (11%) | catalogued as rs1231166833, COSV100872776; called by muse, mutect2, varscan2
- CLHC1 | c.1034T>G p.L345R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV101284864; called by muse, mutect2
- CLIP4 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 88/135 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100191710; called by muse, mutect2, varscan2
- COCH | c.1830C>G p.F610L (on ENST00000216361 / NM_001347720.1; = p.F545L on NM_004086.3) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV53549881, COSV99363520; called by muse, mutect2, varscan2
- COL4A3 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101170174; called by muse, mutect2, varscan2
- COL6A3 | c.4622C>T p.P1541L | Missense Mutation (SNP) | VAF 76/116 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99795955; called by muse, mutect2, varscan2
- COLEC12 | c.2209G>C p.V737L | Missense Mutation (SNP) | VAF 172/433 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101232021; called by muse, mutect2, varscan2
- CPT1C | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV99773346; called by muse, mutect2, varscan2
- CRB1 | c.3006C>A p.S1002R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV100957773; called by muse, mutect2, varscan2
- CRHBP | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV99169464; called by muse, mutect2, varscan2
- CSMD2 | c.3808G>C p.E1270Q | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53874885, COSV99588242; called by muse, mutect2, varscan2
- CTNNA2 | c.2122G>T p.G708C | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559937, COSV58167219, COSV99057391; called by muse, mutect2, varscan2
- CUL4B | c.2497G>T p.E833* | Nonsense Mutation (SNP) | VAF 89/134 reads (66%) | catalogued as COSV100340334; called by muse, mutect2, varscan2
- CYP3A4 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs753292003, COSV100315561, COSV60503753; called by muse, mutect2, varscan2
- DCAF12L2 | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100758529; called by muse, mutect2, varscan2
- DEFA3 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1224602435, COSV100590629; called by muse, mutect2, varscan2
- DICER1 | c.3241G>A p.G1081R | Missense Mutation (SNP) | VAF 70/107 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100601956; called by muse, mutect2, varscan2
- DMBT1 | c.3491G>T p.G1164V (on ENST00000338354 / NM_001377530.1; = p.G665V on NM_004406.3) | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100352604; called by muse, mutect2, varscan2
- DNAH3 | c.3329G>C p.G1110A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV54540883, COSV99766181; called by muse, mutect2, varscan2
- DNAJC30 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99736457; called by muse, mutect2, varscan2
- DOCK8 | c.2677T>A p.S893T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.066); catalogued as COSV101209881; called by muse, mutect2, varscan2
- DPP6 | c.978G>T p.M326I (on ENST00000377770 / NM_001364500.2; = p.M264I on NM_001936.5) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100124391; called by muse, mutect2, varscan2
- DPY19L3 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100639154; called by muse, mutect2
- DSTYK | c.2289G>T p.E763D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100904511; called by muse, mutect2, varscan2
- EGLN3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs749363666, COSV99164314; called by muse, mutect2, varscan2
- EIF2B5 | c.198C>T p.V66= | Splice Region (SNP) | VAF 18/218 reads (8%) | catalogued as COSV99889129; called by muse, mutect2
- EIF4G3 | c.1858G>T p.G620C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99943848; called by muse, mutect2, varscan2
- ENPP1 | c.1104C>A p.Y368* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as COSV100719473, COSV62932481; called by muse, mutect2, varscan2
- EPHA6 | c.2096C>G p.T699S (on ENST00000389672 / NM_001080448.3; = p.T91S on NM_173655.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV101061683; called by muse, mutect2, varscan2
- FAM98A | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99479180; called by muse, mutect2, varscan2
- FAT3 | c.7657A>T p.I2553F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1410994040, COSV99964261; called by muse, mutect2, varscan2
- FAT3 | c.9367G>T p.D3123Y | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99964263; called by muse, mutect2, varscan2
- FCHO1 | c.868C>G p.R290G | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99405983; called by muse, mutect2, varscan2
- FCRL2 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV100829870, COSV63833935; called by muse, mutect2, varscan2
- FLG | c.2948G>A p.R983K | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV100911375; called by muse, mutect2, varscan2
- FOXP4 | c.1355C>T p.S452L (on ENST00000307972 / NM_001012426.1; = p.S439L on NM_138457.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100332567; called by muse, mutect2, varscan2
- FOXR2 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100189453; called by muse, mutect2, varscan2
- FSHR | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as COSV100436857, COSV100438489; called by muse, mutect2, varscan2
- FZR1 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553509; called by muse, mutect2, varscan2
- GABPB2 | c.1318A>G p.R440G | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64461229; called by muse, mutect2, varscan2
- GPATCH4 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.227); catalogued as COSV100576902; called by muse, mutect2
- GPR31 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs745938281, COSV100834114; called by muse, mutect2, varscan2
- GRM5 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100551174; called by muse, mutect2, varscan2
- GTF2H4 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV99461666; called by muse, mutect2, varscan2
- GTF3C5 | c.1226A>G p.Q409R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1296354369, COSV100565352; called by muse, mutect2, varscan2
- H4C12 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100694766, COSV62743886; called by muse, mutect2, varscan2
- H4C5 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV63486336; called by muse, mutect2, varscan2
- HCN1 | c.2618C>A p.S873* | Nonsense Mutation (SNP) | VAF 52/189 reads (28%) | catalogued as COSV57528136; called by muse, mutect2, varscan2
- HS3ST5 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1439776834, COSV100450616, COSV100451129; called by muse, mutect2, varscan2
- HTR5A | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.257); catalogued as rs201305093, COSV55282214, COSV55282708; called by muse, mutect2, varscan2
- IHO1 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99605988; called by muse, mutect2, varscan2
- IL25 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV100197986; called by muse, mutect2, varscan2
- IL5RA | c.856-1G>A p.X286_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99842752, COSV99842821; called by muse, mutect2, varscan2
- INTS14 | c.276A>T p.L92F (on ENST00000313182 / NM_001366360.2; = p.L13F on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100499900; called by muse, mutect2, varscan2
- ITPK1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs150527709, COSV50895874; called by muse, mutect2, varscan2
- KDM5B | c.2261C>G p.S754C | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV99350361; called by muse, mutect2, varscan2
- KIF24 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV100799139; called by muse, mutect2, varscan2
- KMT2B | c.3245A>G p.Q1082R | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99719235; called by muse, mutect2, varscan2
- KMT2D | c.6935C>G p.S2312* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV56410740, COSV56412606; called by muse, mutect2, varscan2
- KRTAP5-3 | c.340C>A p.R114S | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV101294499, COSV68790920; called by muse, mutect2, varscan2
- LFNG | c.880G>A p.G294S (on ENST00000222725 / NM_001040167.2; = p.G165S on NM_002304.2) | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344012698, COSV56069482; called by muse, varscan2
- LILRA5 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100006849; called by muse, mutect2, varscan2
- LMBRD1 | c.1574G>T p.G525V (on ENST00000649011; = p.G503V on NM_018368.4) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100992518; called by muse, mutect2, varscan2
- LRP1B | c.5999C>T p.S2000F | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101254934; called by muse, mutect2
- LUC7L3 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as COSV99536830, COSV99537138; called by muse, mutect2, varscan2
- LYST | c.4086G>C p.L1362F | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV101088889; called by muse, mutect2, varscan2
- MAGEA10 | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as COSV99726668; called by muse, mutect2, varscan2
- MAP2 | c.3214C>T p.L1072F | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV99559057; called by muse, mutect2, varscan2
- MC4R | c.988A>G p.S330G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV100235934; called by muse, mutect2, varscan2
- MEDAG | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs138341583, COSV66850418; called by muse, mutect2, varscan2
- MICAL3 | c.5253G>T p.K1751N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV101490841; called by muse, mutect2, varscan2
- MINK1 | c.2831A>T p.K944M | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99544745; called by muse, mutect2, varscan2
- MUC16 | c.24028G>T p.A8010S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.346); catalogued as COSV101199269; called by muse, mutect2, varscan2
- MYH1 | c.455C>A p.P152Q | Missense Mutation (SNP) | VAF 130/228 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99875431, COSV99876302; called by muse, varscan2
- MYH14 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768069260, COSV99222296; called by muse, mutect2, varscan2
- MYH7 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100805911; called by muse, mutect2, varscan2
- MYT1L | c.2984G>C p.W995S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101217020, COSV67702303; called by muse, mutect2, varscan2
- NADSYN1 | c.1050A>C p.A350= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100034587; called by muse, varscan2
- NCDN | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV100357195; called by muse, mutect2, varscan2
- NDN | c.682T>G p.F228V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100086368; called by muse, mutect2, varscan2
- NOX5 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs773690064, COSV99533598; called by mutect2, varscan2
- NRCAM | c.427A>T p.R143* (on ENST00000379028 / NM_001371124.1; = p.R137* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/141 reads (35%) | catalogued as COSV100694527; called by muse, mutect2, varscan2
- NSD2 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV100373039; called by muse, mutect2, varscan2
- OR10H2 | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as rs57001564, COSV59947186; called by muse, mutect2, varscan2
- OR2L2 | c.302T>A p.F101Y | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100823370; called by muse, mutect2, varscan2
- OR4C46 | c.663C>A p.C221* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100060577; called by muse, mutect2, varscan2
- OR52D1 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100495200; called by muse, mutect2, varscan2
- OR5B3 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100511956; called by muse, mutect2, varscan2
- OR5H14 | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101454124; called by muse, mutect2, varscan2
- OR6Q1 | c.175A>G p.R59G | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs978899424, COSV100109701; called by muse, mutect2, varscan2
- P3H1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99355022; called by muse, mutect2, varscan2
- PABPC1L | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs772962499, COSV99407604; called by muse, mutect2, varscan2
- PAPPA | c.2993T>A p.V998E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100073513; called by muse, mutect2, varscan2
- PARP9 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100830936, COSV100831044; called by muse, mutect2, varscan2
- PATL1 | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100274831; called by muse, mutect2, varscan2
- PATL1 | c.1782G>C p.K594N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100274832; called by muse, mutect2, varscan2
- PCDH1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99745866; called by muse, mutect2, varscan2
- PCDHGA7 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs750393068, COSV99528565; called by muse, mutect2
- PCDHGB1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs751339845, COSV53970008; called by muse, mutect2, varscan2
- PCDHGB2 | c.565C>A p.R189S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99534893, COSV99537156; called by muse, mutect2, varscan2
- PCLO | c.7734A>C p.E2578D | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100430157; called by muse, mutect2, varscan2
- PDE3B | c.2086C>T p.L696F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104388264, COSV99962298; called by muse, mutect2
- PEPD | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99727565; called by muse, mutect2, varscan2
- PGLYRP2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV99483914; called by muse, mutect2, varscan2
- PHF12 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs769477357, COSV100241755; called by muse, mutect2, varscan2
- PHIP | c.5434G>A p.E1812K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99243759; called by muse, mutect2, varscan2
- PKHD1L1 | c.7768A>C p.N2590H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.285); catalogued as COSV101005875; called by muse, mutect2, varscan2
- PKM | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.152); catalogued as rs992450330, COSV58791922; called by muse, mutect2, varscan2
- PLEK | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99310827; called by muse, mutect2
- POM121L12 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.726); catalogued as COSV101374892, COSV68694587; called by muse, mutect2, varscan2
- POTEE | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); catalogued as rs1465383507, COSV100387486, COSV58244533; called by muse, mutect2, varscan2
- PPP1R32 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1161351129, COSV58544695, COSV58545568; called by muse, mutect2, varscan2
- PRRC2B | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1473278841, COSV100621656; called by muse, mutect2, varscan2
- PRSS53 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375690216, COSV54922395; called by muse, mutect2
- PSPC1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV58886721; called by muse, mutect2, varscan2
- REST | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100470842; called by muse, mutect2, varscan2
- ROS1 | c.1849C>G p.Q617E | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100876839; called by muse, mutect2, varscan2
- RSPO3 | c.788A>T p.Q263L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100759522; called by muse, mutect2, varscan2
- SALL4 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1043318739, COSV99409373; called by muse, mutect2, varscan2
- SATB2 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610922; called by muse, mutect2, varscan2
- SCN11A | c.5101G>A p.D1701N | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100181240, COSV56574052; called by muse, mutect2, varscan2
- SDR16C5 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs866265765, COSV100373899; called by muse, mutect2, varscan2
- SELENOP | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs778089674, COSV100736790; called by muse, mutect2, varscan2
- SERPINB11 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101236199; called by muse, mutect2
- SESN1 | c.469G>A p.A157T (on ENST00000356644 / NM_001199933.1; = p.A216T on NM_014454.3) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.724); catalogued as COSV100122733; called by muse, mutect2, varscan2
- SESN3 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.067); catalogued as rs535261299, COSV99565459; called by muse, mutect2
- SH3RF1 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99498889; called by muse, mutect2, varscan2
- SLC10A3 | c.316A>T p.R106W | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as COSV99682056; called by muse, mutect2, varscan2
- SLC16A1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100855909; called by muse, mutect2
- SLC22A13 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100314522; called by muse, mutect2, varscan2
- SLC29A1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs759970566, COSV100505690, COSV100505790; called by muse, mutect2, varscan2
- SLC35B3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV100217249; called by muse, mutect2, varscan2
- SLC35E4 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100299185; called by muse, mutect2, varscan2
- SLC7A13 | c.472T>C p.W158R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV99878732; called by muse, mutect2, varscan2
- SPHKAP | c.4579G>T p.E1527* | Nonsense Mutation (SNP) | VAF 132/191 reads (69%) | catalogued as COSV100763946, COSV60893637; called by muse, mutect2, varscan2
- SPTBN1 | c.5128C>A p.L1710M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100442213; called by muse, mutect2, varscan2
- STARD5 | c.282C>T p.D94= | Splice Region (SNP) | VAF 16/92 reads (17%) | catalogued as rs745566069, COSV100250793; called by muse, mutect2, varscan2
- SYNE1 | c.3991C>A p.Q1331K (on ENST00000367255 / NM_182961.4; = p.Q1338K on NM_033071.3) | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV99558927; called by muse, mutect2, varscan2
- TBCK | c.825G>C p.E275D (on ENST00000273980 / NM_001163436.4; = p.E212D on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99912348; called by muse, mutect2, varscan2
- TCF4 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as COSV100610030; called by muse, mutect2, varscan2
- TCHH | c.1355A>G p.E452G | Missense Mutation (SNP) | VAF 48/134 reads (36%) | PolyPhen benign (0.354); catalogued as COSV100914958; called by muse, mutect2, varscan2
- TFAP2A | c.500C>A p.P167Q (on ENST00000482890; = p.P159Q on NM_001032280.3) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765549775, COSV100116735, COSV60235385; called by muse, mutect2, varscan2
- TGIF1 | c.10C>A p.P4T (on ENST00000330513 / NM_001374396.1; = p.P24T on NM_003244.4) | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1427572371, COSV100394785; called by muse, mutect2
- TIMELESS | c.1033T>C p.F345L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99973804; called by muse, mutect2, varscan2
- TMC2 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 104/182 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369460562; called by muse, mutect2, varscan2
- TMEM132A | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV99134602; called by muse, mutect2
- TMEM132B | c.1780T>C p.W594R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100169119; called by muse, mutect2, varscan2
- TMX3 | c.950A>C p.Q317P | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as COSV100218301; called by muse, mutect2, varscan2
- TRIM33 | c.2629G>A p.D877N | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs994650216, COSV100635167; called by muse, mutect2, varscan2
- TTN | c.102763C>A p.P34255T (on ENST00000591111; = p.P26831T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | PolyPhen possibly damaging (0.88); catalogued as COSV100603568; called by muse, mutect2, varscan2
- TTN | c.79341C>G p.S26447R (on ENST00000591111; = p.S19023R on NM_003319.4) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | PolyPhen benign (0.232); catalogued as COSV100603571; called by muse, mutect2, varscan2
- UBQLN1 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV99973258; called by muse, mutect2, varscan2
- UGT2A1 | c.997-1G>A p.X333_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as rs139337193; called by muse, mutect2, varscan2
- USH2A | c.98C>A p.S33* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100232365; called by muse, mutect2, varscan2
- USP31 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); catalogued as COSV54849010, COSV54851799; called by muse, mutect2, varscan2
- VPS13C | c.3205C>G p.L1069V (on ENST00000644861 / NM_020821.3; = p.L1026V on NM_017684.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.124); catalogued as COSV99827950; called by muse, mutect2, varscan2
- WDR27 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.519); catalogued as COSV100358562; called by muse, mutect2, varscan2
- WFS1 | c.1105A>T p.K369* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99901143; called by muse, mutect2, varscan2
- WNK1 | c.3326G>T p.R1109L (on ENST00000315939 / NM_018979.4; = p.R862L on NM_014823.3) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266873; called by muse, mutect2
- XIRP2 | c.8788G>C p.D2930H (on ENST00000628543; = p.D3105H on NM_152381.6) | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as rs369944055; called by muse, mutect2, varscan2
- ZBED9 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV71729455; called by muse, mutect2, varscan2
- ZDHHC20 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100203378, COSV57184050; called by muse, mutect2, varscan2
- ZFC3H1 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs886420918, COSV57348213, COSV57349287; called by muse, mutect2, varscan2
- ZFHX4 | c.4414G>T p.E1472* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99257268; called by muse, mutect2, varscan2
- ZFHX4 | c.4775C>A p.P1592H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99260747; called by muse, mutect2, varscan2
- ZFP82 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV101088981; called by muse, mutect2
- ZIC1 | c.910T>A p.C304S | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99291751; called by muse, mutect2, varscan2
- ZNF471 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as COSV100340490; called by muse, mutect2, varscan2
- ZNF92 | c.225A>G p.P75= (on ENST00000328747 / NM_152626.4; = p.P6= on NM_007139.4) | Splice Region (SNP) | VAF 35/118 reads (30%) | catalogued as COSV60874195; called by muse, mutect2, varscan2
- ABCA3 | c.3583del p.L1195Sfs*4 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- ARHGAP31 | c.1343del p.P448Qfs*37 | Frame Shift Del (DEL) | VAF 55/140 reads (39%) | called by mutect2, pindel, varscan2
- FCGBP | c.10510C>T p.P3504S | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GALNT17 | c.1724dup p.L576Pfs*19 | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- KCND3 | c.365del p.G122Afs*67 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- MYO7B | c.3356_3357del p.S1119* | Frame Shift Del (DEL) | VAF 55/107 reads (51%) | called by mutect2, pindel, varscan2
- SHH | c.108dup p.K37Qfs*27 | Frame Shift Ins (INS) | VAF 52/154 reads (34%) | called by pindel, varscan2
- ZNF676 | c.652T>C p.Y218H (on ENST00000650058; = p.Y186H on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ACRBP | c.1197C>A p.S399= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99976043; called by muse, mutect2, varscan2
- ANKS3 | c.1041C>G p.P347= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs373861926, COSV100423016; called by muse, mutect2
- ARID1A | c.5451A>G p.V1817= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100251022; called by muse, mutect2, varscan2
- CACNA1I | c.363C>T p.F121= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV60803432; called by muse, mutect2, varscan2
- CALCOCO1 | c.1815C>T p.V605= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100017242; called by muse, mutect2, varscan2
- CATSPERG | c.2898C>T p.D966= | Silent (SNP) | VAF 57/848 reads (7%) | catalogued as rs2302184; called by muse, mutect2
- CD1A | c.738C>A p.G246= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV99192268; called by muse, mutect2, varscan2
- CTRL | c.663G>A p.Q221= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as rs765267708, COSV52124428, COSV99344572; called by muse, mutect2, varscan2
- EPHA3 | c.2799G>A p.T933= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs761761984, COSV100346865, COSV60705893; called by muse, mutect2, varscan2
- FARP2 | c.1731G>A p.T577= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs768579504, COSV50870896, COSV99884336; called by muse, mutect2, varscan2
- FBXO24 | c.1434C>T p.S478= (on ENST00000241071 / NM_033506.3; = p.S516= on NM_012172.5) | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1448659562, COSV99575149; called by muse, mutect2, varscan2
- FCGBP | c.7035C>G p.L2345= | Silent (SNP) | VAF 82/259 reads (32%) | called by muse, mutect2, varscan2
- FCRL4 | c.15G>A p.A5= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs144040210; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.702G>T p.L234= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as COSV100436226; called by muse, mutect2, varscan2
- GDNF | c.462A>T p.T154= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV100427397; called by muse, mutect2, varscan2
- GDPD5 | c.1446C>T p.S482= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100409223; called by muse, mutect2, varscan2
- GID4 | c.303G>A p.A101= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV99254108; called by muse, mutect2, varscan2
- GRIA1 | c.2512C>A p.R838= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as COSV99599047; called by muse, mutect2, varscan2
- IL18BP | c.69C>T p.V23= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs373119758, COSV99474589; called by muse, mutect2, varscan2
- LILRA2 | c.1323C>T p.H441= (on ENST00000391738 / NM_001130917.3; = p.H424= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs180870681, COSV99253108; called by muse, mutect2, varscan2
- LTF | c.747C>A p.L249= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV51608943, COSV99207507; called by muse, mutect2, varscan2
- MFNG | c.585C>T p.A195= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1202131929, COSV100812874; called by muse, mutect2, varscan2
- MMD2 | c.519C>A p.G173= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV101286976, COSV68660247; called by muse, mutect2, varscan2
- MRO | c.663T>C p.D221= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99839116; called by muse, mutect2, varscan2
- MYOM2 | c.39T>C p.H13= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100037226; called by muse, mutect2, varscan2
- NFE2 | c.207A>G p.S69= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV100380709; called by muse, mutect2
- OAS1 | c.417C>G p.L139= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs754283775, COSV99177097; called by muse, mutect2, varscan2
- OR2B2 | c.699T>C p.G233= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs1329664592, COSV100308092; called by muse, mutect2, varscan2
- OR2W3 | c.765C>T p.I255= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV100831648, COSV64457122; called by muse, mutect2, varscan2
- OR52A1 | c.345C>A p.G115= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV100200456, COSV61092033; called by muse, mutect2, varscan2
- PDE3B | c.2088C>T p.L696= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1252056365, COSV99962301; called by muse, mutect2
- PDK2 | c.357C>T p.I119= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99142935; called by muse, varscan2
- PHACTR4 | c.1047T>A p.T349= (on ENST00000373839 / NM_001350159.2; = p.T359= on NM_023923.4) | Silent (SNP) | VAF 12/219 reads (5%) | catalogued as COSV100868423; called by muse, mutect2
- PLEKHG4B | c.3111G>T p.V1037= (on ENST00000283426; = p.V1393= on NM_052909.5) | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV99360067; called by muse, mutect2, varscan2
- POC1B | c.249C>T p.T83= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs772559970, COSV57970868; called by muse, mutect2, varscan2
- PRAMEF15 | c.939G>A p.L313= | Silent (SNP) | VAF 100/415 reads (24%) | called by muse, mutect2, varscan2
- PRPF39 | c.246A>G p.E82= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100866000; called by muse, mutect2, varscan2
- PTPRT | c.345C>T p.S115= | Silent (SNP) | VAF 50/75 reads (67%) | catalogued as COSV100626375; called by muse, mutect2, varscan2
- RNF214 | c.150G>A p.L50= | Silent (SNP) | VAF 77/139 reads (55%) | catalogued as COSV100326589; called by muse, mutect2, varscan2
- SBNO2 | c.2904C>T p.F968= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs1477955960, COSV100684342; called by muse, mutect2, varscan2
- SPRY3 | c.807G>A p.V269= | Silent (SNP) | VAF 89/180 reads (49%) | catalogued as COSV100249267; called by muse, mutect2, varscan2
- TM9SF4 | c.1344C>G p.T448= | Silent (SNP) | VAF 48/1204 reads (4%) | catalogued as COSV99454275; called by muse, mutect2
- TNN | c.195C>T p.L65= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs754891519, COSV99511595; called by muse, mutect2, varscan2
- TOGARAM2 | c.720C>T p.I240= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV101091024; called by muse, mutect2, varscan2
- TSPAN11 | c.438G>A p.V146= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99666796; called by muse, mutect2, varscan2
- XAB2 | c.2034C>G p.L678= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV99350263; called by muse, mutect2, varscan2
- XKR3 | c.1140G>C p.V380= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- ZFHX3 | c.2832C>G p.L944= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99196511; called by muse, mutect2, varscan2
- ZIM2 | c.669C>T p.D223= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as rs777971871, COSV99688234; called by muse, mutect2, varscan2
- ZNF185 | c.762G>A p.A254= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs140454766, COSV59278866; called by muse, mutect2, varscan2
- ZNF556 | c.1122G>T p.T374= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs371373885, COSV56912032; called by muse, mutect2, varscan2
- ZXDC | c.2100C>G p.L700= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100306391; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498989 T>C | 5'Flank (SNP) | VAF 45/133 reads (34%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- TGIF1 | c.-48A>T | 5'UTR (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100394783; called by muse, mutect2, varscan2
- TMC5 | c.1049-3364T>G | Intron (SNP) | VAF 31/48 reads (65%) | catalogued as COSV99572315; called by muse, mutect2, varscan2
- TP73-AS1 | n.1366G>A | RNA (SNP) | VAF 23/84 reads (27%) | catalogued as rs765615417; called by muse, mutect2, varscan2
